Surgical pathology report (de-identified scan), TCGA case TCGA-G9-7510, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-G9-7510-01A (Primary Tumor).

[page 1 of 2]
SPECIMENS:

- A. PROSTATE
- B. LEFT PELVIC LYMPH NODES
- C. RIGHT PELVIC LYMPH NODES

SPECIMEN(S):

- A. PROSTATE
- B. LEFT PELVIC LYMPH NODES
- C. RIGHT PELVIC LYMPH NODES

DIAGNOSIS:

- A. PROSTATE, PROSTATECTOMY:
- PROSTATIC ADENOCARCINOMA, GLEASON SCORE: 4+4=8/10 WITH A MINOR COMPONENT OF 5, INVOLVING 25% OF PROSTATE GLAND, RIGHT AND LEFT LOBES (APEX, ANTERIOR, POSTERIOR).
- PERINEURAL INVASION IS IDENTIFIED.
- LYMPHOVASCULAR INVASION IS NOT SEEN.
- MICROSCOPIC FOCUS OF EXTRAPROSTATIC EXTENSION INTO FAT IS IDENTIFIED, RIGHT POSTERIOR CAPSULE.
- SEMINAL VESICLES ARE UNINVOLVED BY TUMOR.
- MICROSCOPIC FOCUS OF TUMOR IS SEEN ADJACENT TO RIGHT ANTERIOR CAPSULE MARGIN (LINEAR DISTANCE OF <1 MM)
- B. LYMPH NODE, LEFT PELVIC, EXCISION:
- SEVEN LYMPH NODES, NEGATIVE FOR CARCINOMA (0/7).
- C. LYMPH NODE, RIGHT PELVIC, EXCISION:
- THREE LYMPH NODES, NEGATIVE FOR CARCINOMA (0/3).

SYNOPTIC REPORT - PROSTATE GLAND

Specimens Involved

Specimens: A: PROSTATE

B: LEFT PELVIC LYMPH NODES

C: RIGHT PELVIC LYMPH NODES

Location: Left

Right

Posterior lateral

Apical

WHO CLASSIFICATION

Epithelial tumors

Adenocarcinoma 8140/3

Multicentricity: Yes

Gland Involvement: 25%

Gleason Grade/Sum:: Grade 4 + 4 , Sum 8 /10; Tertiary grade 5

High Grade PIN Present: Yes

Perineural Invasion: Yes

Vascular/Lymphatic Invasion: No

Seminal Vesicle Invasion: No

Periprostatic Fat Involved: Yes

Details: right posterior capsule level II (A12), microscopic focus

Bladder Neck Involved: No

Margins Involvement: Yes

Location: right anterior capsule level II (A11)

Linear Distance: Microscopic (<1mm)

Frozen Performed: No

Post Hormonal Therapy Change: No

Lymph Nodes: Negative Right 0 / 3 Left 0 / 7

Other Pathologic Findings: None identified

Pathological Staging (pTNM): T 3a N 0 M x

Pathological staging is based on the AJCC Cancer Staging Manual, 7th Edition

[page 2 of 2]
pT3a: Extraprostatic extension or microscopic invasion of bladder neck.
pMX: Cannot be assessed

GROSS DESCRIPTION:

A. PROSTATE

Received fresh is a 35g resected prostate measuring 5.5cm from right to left, 4.5 cm from anterior to posterior, and 3.2cm from apex to base, with attached right and left seminal vesicles and vas deferens. The specimen is inked as follows: Anterior-Orange, Posterior-Black, Apex-Red, Base-Blue, Right-Green, and Left-Yellow. After removal of the apex and base, the remaining prostate weight is 17g. The specimen is serially sectioned from apex to base to reveal firm tan fibrous parenchyma. A 1 x 0.8cm area of tan brown granules is identified in the left mid portion of the specimen. The granules are 0.1cm each. The attached right and left seminal vesicles are 5.5 x 1.8 x 1cm and 6.5 x 2.2 x 0.7cm, respectively, are sectioned to beige tan cystic tissue with no gross evidence of tumor involvement. The attached right and left segments of vas deferens are 3.6 x 0.5cm and 3 x 0.7cm, respectively, are sectioned to reveal firm tan tubular structure with no gross evidence of tumor involvement. A portion of the specimen is submitted for tissue procurement (Level II). The remainder of the specimen is submitted as follows:

A1-A2: right apex
A3-A4: left apex
A5: level I right anterior
A6-A7: level I right posterior
A8: level I left anterior
A9-A10: level I left posterior
A11: level II right anterior capsule
A12: level II right posterior capsule
A13: level II left anterior capsule
A14: level II left posterior capsule
A15: level III right anterior
A16: level III right posterior
A17: level III left anterior
A18: level III left posterior
A19-A20: right base with periurethral margin
A21: left base with periurethral margin
A22-A23: right lateral base
A24: left lateral base
A25: right seminal vesicle and vas deferens
A26: left seminal vesicle and vas deferens

B. LEFT PELVIC LYMPH NODES

Received in formalin labeled with the patient's identification and 'left pelvic lymph nodes' are seven tan pink lymph nodes ranging from 0.3 x 0.2 x 0.2cm to 3.4 x 2 x 1.8cm.

B1: four lymph nodes
B2: two lymph nodes
B3-B4: one lymph node

C. RIGHT PELVIC LYMPH NODES

Received in formalin labeled with the patient's identification and 'right pelvic lymph nodes' are three tan pink lymph nodes ranging from 0.5 x 0.4 x 0.3cm to 5.4 x 2.3 x 1.5cm.

C1: two lymph nodes
C2-C4: one lymph node

CLINICAL HISTORY:

None provided.

PRE-OPERATIVE DIAGNOSIS:

Prostate carcinoma.

Gross Dictation: [REDACTED]

Microscopic/Diagnostic Dictation:., Pathologist [REDACTED]

Final Review:., Pathologist, [REDACTED]

Final: Pathologist, [REDACTED]

Source: NCI Genomic Data Commons file a2e7e230-9d77-40bd-9940-fb98cfcb9cdf (TCGA-G9-7510.11C8711A-57C0-41FE-82FA-2E9592FEF570.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).